CCDI case PBCGAV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/bfc99cfa-8c77-4e22-bea5-a5dc22892ab5

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,033 days).

Biospecimens (3 samples)
- Sample 0DRB5I: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRB5P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DRB5W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
